Gene-level copy-number profile of tumor specimen TCGA-3A-A9J0-01A from TCGA case TCGA-3A-A9J0, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.2 years (27,453 days).
Specimen TCGA-3A-A9J0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.784b304a-c14f-451f-bd43-7f53efa2a665.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9J0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8cf6418b-35aa-4d2b-946c-7086a85d2864

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 178; copy number 1: 3,855; copy number 2: 12,433; copy number 3: 20,325; copy number 4: 18,283; copy number 5: 3,665; copy number 6: 953; copy number 7: 15; copy number 8: 80; copy number 16: 15; copy number 22: 3; copy number 67: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9J0-01A-11D-A40V-01): tumor purity 0.48, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 178 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:25,909,503–25,911,234, 1 gene: MSNP1.
- chr9:21,321,300–22,029,594, 28 genes (within-gene range 0–2): IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:92,711,363–92,921,560, 11 genes: BICD2, AL136981.3, AL136981.4, ANKRD19P, RNU6-714P, EEF1DP2, AL136981.2, ZNF484, AL136981.1, SNX18P2, ALOX15P2.
- chr17:12,201,600–12,395,177, 2 genes: AC005244.2, AC084167.1.
- chr18:50,879,080–50,988,121, 3 genes: ME2, Y_RNA, ELAC1.
- chr18:74,073,353–80,247,514, 130 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 128 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,986,138–82,808,021, 3 genes, copy number 22 (within-gene range 4–22): LINC02008, RPL7AP23, CYP51A1P1.
- chr15:85,958,717–87,703,852, 15 genes, copy number 7: AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr15:98,437,162–101,614,531, 80 genes, copy number 8 (broad region; genes not listed).
- chr17:30,956,280–31,382,116, 15 genes, copy number 16 (within-gene range 3–16): AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1.
- chr17:39,603,536–39,877,896, 15 genes, copy number 67: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.

Autosomal genes at a single copy (total copy number 1): 1,468. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
